Gene-level copy-number profile of tumor specimen TCGA-CC-A7IG-01A from TCGA case TCGA-CC-A7IG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 47.8 years (17,453 days).
Specimen TCGA-CC-A7IG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.084914c7-efae-48f2-bffc-54788cd9053b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A7IG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6702e97e-b11f-4b7d-9a76-20a8c39f70aa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,519; copy number 2: 34,839; copy number 3: 8,388; copy number 4: 5,535; copy number 5: 222; copy number 6: 312.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A7IG-01A-11D-A33B-01): tumor purity 0.59, ploidy 6.43, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 534 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:61,240,898–71,652,611, 94 genes, copy number 5 (broad region; genes not listed).
- chr6:72,621,792–74,690,727, 37 genes, copy number 5 (within-gene range 3–5): KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7, AL357507.1, AL357563.1.
- chr13:53,815,419–56,054,397, 14 genes, copy number 5: LINC00558, LINC00458, AL356052.1, MIR1297, RPL13AP25, AL442636.1, AL512655.1, AL390964.1, LINC02335, AL139038.1, MIR5007, AL354821.1, HNF4GP1, AL138997.1.
- chr13:84,520,103–104,134,257, 245 genes, copy number 5–6 (broad region; genes not listed).
- chr13:108,480,226–114,337,626, 122 genes, copy number 6 (broad region; genes not listed).
- chr17:20,595,531–21,002,276, 22 genes, copy number 5 (within-gene range 3–5): AC087499.3, AC087499.1, AC087499.4, LINC02088, AC087499.7, AC087499.5, AC087499.6, AC087499.2, RNFT1P3, HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2, ABHD17AP6, CCDC144NL, AC090774.2, CCDC144NL-AS1, RNU6-1178P, RNASEH1P1, AC090774.1, SPECC1P2.

Autosomal genes at a single copy (total copy number 1): 8,132. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
